Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A48O, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A48O-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Clinical Diagnosis & History:

year old with large retroperitoneal mass.

Specimens Submitted:

1: SP: Right colon, cecum, and appendix and right radical resection, retroperitoneal sarcoma

DIAGNOSIS:

1. RIGHT COLON, CECUM, APPENDIX, RETROPERITONEAL SARCOMA, RESECTION:
- HIGH GRADE LEIOMYOSARCOMA WITH FOCAL AREAS OF NECROSIS.
- TUMOR SIZE IS 17 X 12 X 7 CM.
- TUMOR IS COVERED GROSSLY BY AN INTACT THIN MEMBRANE AND ADIPOSE TISSUE, REPRESENTING SURGICAL MARGIN.
- ADHERENT SEGMENT OF COLON IS FREE OF TUMOR.
- APPENDIX WITH FIBROUS OBLITERATION.

NOTE: TUMOR CELLS ARE POSITIVE FOR DESMIN AND SMA, NEGATIVE FOR S100 AND CD117, SUPPORTING THE DIAGNOSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh labeled, "right colon, cecum and appendix and right radical resection retroperitoneal sarcoma", and consists of soft tissue mass with attached fragment of right colon, cecum and appendix. Soft tissue mass measures 17 x 12 x 7 cm, covered with thin membrane and adipose tissue. Serial sectioning of the mass reveals tan white, fibrotic and whorled surface, with focal hemorrhage. No necrosis is grossly identified. The attached colon and cecum measure 27cm length, 6.0 cm in circumference and 0.2 cm in thickness with focal ruptured area, and otherwise unremarkable mucosa and serosa. The appendix measures 7.0 x 0.5 cm, grossly unremarkable.

** Continued on next page **

ICD-O-3

leiomyosarcoma, NOS
8890/3

Site:

retroperitoneum

9-11-12
EP

C48.0

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Accession #: [REDACTED]

----- Page 2 of 2
Representative sections are submitted for TPS and permanent sections.
Photograph is taken.

Summary of sections:

TM-tumor mass
SM-surface membrane
CM-cecum margin
COM-colon margin
RUP-ruptured area of colon
R-representative section of colon
A-appendix

Summary of Sections:

Part 1: SP: Right colon, cecum, and appendix and right radical resection,
retroperitoneal sarcoma

Block	Sect.	Site	PCs
1		A	1
1		CM	1
1		COM	1
1		R	1
1		RUP	1
1		SM	1
10		TM	10

** End of Report **

HPA Discrepancy		
Initial/Synchronous Primary Noted		
Reviewed Initials	8/1/12	W 8/1/12

Source: NCI Genomic Data Commons file d499a3c0-7eb2-481f-a9e2-6e9e8cec0ec7 (TCGA-DX-A48O.80AF2F38-D021-4615-B4F7-C94E9813D4DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).